CGCI case BLGSP-71-06-00277 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0196393b-aa14-432c-bfcc-1f858c14cd4f

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: hispanic or latino; Age at index: 11 years; Vital status: Dead; Days to death: 310 days.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Lymph nodes of head, face and neck; Classification of tumor: primary; Age at diagnosis: 11.1 years (4,051 days); Year of diagnosis: 2016; Method of diagnosis: Incisional Biopsy; Ann Arbor pathologic stage: Stage II; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 310 days; Ann Arbor extranodal involvement: Yes; Burkitt lymphoma clinical variant: Endemic; Max tumor bulk site: Mandible; Sites of involvement: Mandible / Lymph node, NOS.
   Pathology details: Lymph node involved site: Submandibular.
   Pathology details: Lymph node involved site: Splenic; Tumor largest dimension diameter: 14 cm.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: COM; Days to treatment start: 12 days; Days to treatment end: 90 days; Number of cycles: 6; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Methotrexate + Vincristine; Initial disease status: Initial Diagnosis; Days to treatment start: 12 days; Days to treatment end: 90 days; Number of cycles: 6; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Progressive Disease; Regimen or line of therapy: DHAP; Days to treatment start: 174 days; Days to treatment end: 295 days; Number of cycles: 6; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Cytarabine + Dexamethasone; Initial disease status: Progressive Disease; Days to treatment start: 174 days; Days to treatment end: 295 days; Number of cycles: 6; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Radiation Therapy, NOS; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (3 entries)
- Days to follow up: 0 days; Disease response: With Tumor; Karnofsky performance status: 80; ECOG performance status: 1.
- Days to follow up: 126 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Bones of skull and face and associated joints; Days to recurrence: 126 days.
- Days to follow up: 310 days; Disease response: With Tumor.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Positive.
- Lactate Dehydrogenase 431 [Blood test normal range upper: 298].

Other clinical attributes
- Day 0: Weight: 20 kg; Height: 126 cm; BMI: 12.6.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-06-00277-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Other; Preservation method: Frozen; Days to sample procurement: 0 days; Method of sample procurement: Incisional Biopsy; Tissue collection type: Prospective.
  Slide BLGSP-71-06-00277-01A-01-S1-HE: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 30; Percent neutrophil infiltration: 5.
  Slide BLGSP-71-06-00277-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 5.
- Sample BLGSP-71-06-00277-01Z: Sample type: Tumor; Tissue type: Tumor.
  Slide BLGSP-71-06-00277-01-CD10: Tissue microarray coordinates: C2,E4,B6.
  Slide BLGSP-71-06-00277-01-Ki67: Tissue microarray coordinates: C2,E4,B6.
  Slide BLGSP-71-06-00277-01-CD20: Tissue microarray coordinates: C2,E4,B6.
  Slide BLGSP-71-06-00277-01-BCL2: Tissue microarray coordinates: C2,E4,B6.
  Slide BLGSP-71-06-00277-01-CD3: Tissue microarray coordinates: C2,E4,B6.
  Slide BLGSP-71-06-00277-01-HE-1: Tissue microarray coordinates: C2,E4,B6.
  Slide BLGSP-71-06-00277-01-BCL6: Tissue microarray coordinates: C2,E4,B6.
- Sample BLGSP-71-06-00277-12A: Sample type: Buccal Cell Normal; Tissue type: Normal; Specimen type: Buccal Cells; Preservation method: Frozen; Days to sample procurement: 0 days; Method of sample procurement: Other; Tissue collection type: Prospective.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: With tumor; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Extranodal site involvement: 2; Extranodal involvment other: Multilpe lymphnodes; Lymph nodes examined: No.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- Tests performed: LDH level: 431; Immunophenotypic analysis method: Immunohistochemistry.
- Follow-up form: Tumor status: With tumor; New tumor event diagnosis indicator: Yes.
- Follow-up form, New tumor event: New tumor event type: Locoregional Recurrence; New tumor event site other: New jaw tumor; New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.
- Treatments, Treatment 1: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharma adjuvant cycles count: 6; Treatment best response: Clinical Progressive Disease.
- Treatments, Treatment 2: Therapy regimen: Progression after initial; Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharma adjuvant cycles count: 6; Treatment best response: Clinical Progressive Disease.
